Somatic mutation profile of tumor specimen TARGET-30-PASWLY-01A (aliquot TARGET-30-PASWLY-01A-01D) from TARGET case TARGET-30-PASWLY, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 2.7 years (979 days).
Specimen TARGET-30-PASWLY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 41a8e16d-b2fc-4378-9489-5fc61137a877.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PASWLY-10A (Blood Derived Normal), aliquot TARGET-30-PASWLY-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9e76bb35-f5b5-426e-a3a6-cb55ac22d9a9

The open-access MAF lists 6 somatic variants for this specimen: 6 protein-altering or splice-affecting.
By variant classification: Missense Mutation 5, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AR | c.2132G>T p.R711I | Missense Mutation (SNP) | VAF 12/15 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as CM000304, COSV65953299; called by muse, mutect2, varscan2
- KCNJ9 | c.687C>G p.S229R | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.33); catalogued as COSV63631465; called by muse, mutect2
- LAMA1 | c.645G>C p.L215F | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67532506; called by muse, mutect2, varscan2
- LINGO2 | c.92G>A p.R31H | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as rs906339987, COSV58057254, COSV58061032; called by muse, mutect2, varscan2
- PNPLA2 | c.691C>T p.P231S | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.806); catalogued as COSV60743814; called by muse, mutect2
- YLPM1 | c.685C>T p.Q229* | Nonsense Mutation (SNP) | VAF 43/128 reads (34%) | catalogued as COSV53106749; called by muse, mutect2, varscan2
